Gene-level copy-number profile of tumor specimen HTMCP-02-07-01066-01A from CGCI case HTMCP-02-07-01066, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Vital status: Alive; Primary diagnosis: Non-small cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 52.0 years (19,006 days).
Specimen HTMCP-02-07-01066-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 919a4ed8-439f-45c5-8f39-c905dff678fb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-07-01066-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/444aa534-b962-4a22-bd0b-2bc4288dc79d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 373; copy number 1: 4,256; copy number 2: 21,600; copy number 3: 20,177; copy number 4: 5,519; copy number 5: 4,237; copy number 6: 2,062; copy number 7: 128; copy number 8: 70; copy number 9: 108; copy number 10: 253; copy number 11: 35; copy number 12: 10; copy number 14: 4; copy number 15: 4; copy number 16: 7; copy number 17: 20; copy number 18: 10; copy number 20: 10; copy number 22: 5; copy number 28: 6; copy number 36: 10; copy number 66: 3.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr17:46,372,855–46,579,691, 6 genes: NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,918 genes in 62 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:19,074,510–19,819,502, 22 genes, copy number 5 (within-gene range 3–5): UBR4, EMC1-AS1, EMC1, MRTO4, AKR7L, AKR7A3, AL035413.1, AKR7A2, RNU6-1099P, SLC66A1, CAPZB, RN7SL277P, MICOS10, RNU4-28P, AL031727.2, NBL1, MICOS10-NBL1, AL031727.1, HTR6, TMCO4, RNF186, AL391883.1.
- chr1:143,419,625–171,824,959, 1,043 genes, copy number 6–9 (broad region; genes not listed).
- chr1:177,923,956–208,255,376, 554 genes, copy number 5–6 (broad region; genes not listed).
- chr1:209,147,220–240,013,226, 596 genes, copy number 5–6 (broad region; genes not listed).
- chr1:241,497,603–241,999,098, 12 genes, copy number 6: FH, KMO, OPN3, CHML, AL133390.1, WDR64, AL365366.1, EXO1, RPL23AP20, BECN2, CFL1P4, MAP1LC3C.
- chr1:242,975,005–247,492,415, 99 genes, copy number 6 (broad region; genes not listed).
- chr2:94,725,674–103,019,900, 220 genes, copy number 5 (broad region; genes not listed).
- chr2:105,038,069–106,544,297, 31 genes, copy number 5 (within-gene range 4–5): MRPS9, MRPS9-AS1, LINC01918, GPR45, AC012360.2, TGFBRAP1, AC012360.1, AC012360.3, C2orf49, FHL2, AC108058.1, NCK2, AC010978.1, AC009505.1, ECRG4, UXS1, AC018878.1, AC092106.1, RPL22P10, SRSF3P4, RPS21P2, RPL27AP4, ILRUNP1, AC114755.1, ANAPC1P6, PLGLA, RGPD3, AC097527.1, CD8B2, AC108868.2, AC108868.1.
- chr2:107,754,112–113,962,596, 178 genes, copy number 5 (broad region; genes not listed).
- chr2:117,754,139–121,809,962, 67 genes, copy number 5 (broad region; genes not listed).
- chr2:126,656,133–128,519,177, 51 genes, copy number 5: GYPC, AC013474.1, RNU6-675P, TEX51, RNU7-182P, AC012508.2, AC012508.3, AC012508.1, BIN1, NIFKP9, CYP27C1, WBP11P2, ERCC3, AC068282.1, MAP3K2, RNU6-1147P, MAP3K2-DT, PROC, MIR4783, IWS1, AC010976.1, RNU4-48P, MYO7B, AC010976.2, LIMS2, GPR17, WDR33, SFT2D3, RNY4P7, Y_RNA, ZFP91P1, POLR2D, RNU6-395P, RPS26P19, Metazoa_SRP, AMMECR1L, AC012306.2, AC012306.1, SAP130, AC108059.2, Y_RNA, UGGT1, SRMP3, AC108059.1, DYNLT3P2, RPL14P6, RPL21P34, HS6ST1, Y_RNA, RNA5SP103, ISCA1P6.
- chr2:134,735,464–136,390,669, 28 genes, copy number 5: CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590, CCNT2, MAP3K19, RAB3GAP1, SNORA40B, ZRANB3, G3BP1P1, R3HDM1, RNU6-512P, MIR128-1, UBXN4, LCT, Y_RNA, LCT-AS1, MCM6, MANEALP1, DARS1, DARS-AS1, AC068492.1, CXCR4, HNRNPKP2, AC112255.1, UBBP1, RN7SKP141.
- chr2:137,715,332–140,131,780, 25 genes, copy number 5: Y_RNA, HNMT, LINC01832, RPL15P5, YWHAEP5, IDI1P1, RNF14P1, AC114763.1, AC114763.2, SPOPL, AC092620.1, AC092620.2, LINC02631, NXPH2, RN7SKP286, YY1P2, AHCYP4, AC062021.1, AC016710.1, SNORA72, MRPS18BP2, RPL9P13, AC078851.1, RN7SL283P, LINC01853.
- chr2:140,586,626–182,131,398, 550 genes, copy number 5 (broad region; genes not listed).
- chr3:164,670,878–198,123,232, 622 genes, copy number 5–6 (broad region; genes not listed).
- chr4:51,843,000–68,497,604, 219 genes, copy number 5–9 (broad region; genes not listed).
- chr4:68,704,600–79,877,770, 223 genes, copy number 10–20 (broad region; genes not listed).
- chr4:186,587,794–188,681,051, 27 genes, copy number 5 (within-gene range 4–5): FAT1, AC107050.1, AC108865.1, AC108865.2, MRPS36P2, AC110772.1, AC110772.2, LINC02374, AC097652.1, LINC02514, LINC02515, AC093763.2, AC093763.1, LINC02492, AC097521.1, ADAM20P3, AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060.
- chr5:58,198–612,210, 24 genes, copy number 5: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1.
- chr5:8,207,019–45,895,970, 526 genes, copy number 5–6 (broad region; genes not listed).
- chr5:179,550,554–180,087,038, 29 genes, copy number 6: RUFY1, PRDX2P3, RUFY1-AS1, HNRNPH1, Metazoa_SRP, C5orf60, AC136604.1, AC136604.2, CBY3, CANX, HMGB3P22, MAML1, LTC4S, MGAT4B, MIR1229, SQSTM1, MRNIP, RN7SKP150, Y_RNA, AC008393.1, TBC1D9B, RNF130, RPS15AP18, AC010285.2, AC010285.1, AC010285.3, MIR340, AC122713.2, AC122713.1.
- chr7:726,699–35,259,729, 580 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:54,185,071–56,116,417, 53 genes, copy number 5–7: AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2.
- chr7:71,779,491–73,832,693, 61 genes, copy number 5–7 (broad region; genes not listed).
- chr7:142,500,028–142,793,368, 44 genes, copy number 6: TRBV5-6, TRBV6-8, TRBV7-7, TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr12:30,628,988–31,106,830, 13 genes, copy number 5: IPO8, CAPRIN2, AC010198.1, LINC00941, AC010198.2, PPIAP44, TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3.
- chr13:30,022,021–30,996,138, 28 genes, copy number 5: AL354674.1, LINC00365, LINC00384, LINC00385, AL157770.1, KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, LINC01058, UBE2L5, HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066.
- chr14:21,829,539–22,516,331, 95 genes, copy number 5–8 (broad region; genes not listed).
- chr14:28,318,141–34,462,774, 85 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr14:34,432,788–35,317,493, 34 genes, copy number 5–6: SPTSSA, RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP, RNU6-1261P, RPL23AP8, CFL2, RPL12P6, BAZ1A, RNU7-41P, AL121603.2, SRP54-AS1, AL121603.1, IGBP1P1, SRP54, FAM177A1, PPP2R3C, AL049776.1, PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6.
- chr17:66,895,491–70,629,265, 88 genes, copy number 5–9 (broad region; genes not listed).
- chr17:80,991,598–81,309,248, 23 genes, copy number 5: CHMP6, AC127496.6, AC127496.7, AC127496.5, AC127496.2, BAIAP2-DT, BAIAP2, AATK, MIR657, MIR3065, MIR338, MIR1250, AC115099.1, PVALEF, CEP131, AC027601.2, TEPSIN, AC027601.1, NDUFAF8, SLC38A10, AC027601.3, AC027601.4, LINC00482.
- chr18:1,509,022–4,455,307, 53 genes, copy number 5 (within-gene range 4–5): AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66.
- chr18:5,381,641–13,827,323, 202 genes, copy number 5 (broad region; genes not listed).
- chr18:23,453,287–25,056,760, 40 genes, copy number 5: RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1.
- chr19:7,382,834–7,943,667, 47 genes, copy number 5 (within-gene range 3–5): AC008878.3, AC119396.2, ARHGEF18, PEX11G, TEX45, AC008878.1, ZNF358, AC008878.4, MCOLN1, AC008878.2, PNPLA6, CAMSAP3, MIR6792, XAB2, PET100, AC008763.2, PCP2, AC008763.1, STXBP2, RPS27AP19, RETN, MCEMP1, AC008763.3, TRAPPC5, FCER2, CLEC4G, AC008763.4, CD209, RPL21P129, CLEC4M, CLEC4GP1, EXOSC3P2, EVI5L, PRR36, AC010336.3, LYPLA2P2, 5S_rRNA, LRRC8E, AC010336.1, MAP2K7, AC010336.4, TGFBR3L, AC010336.2, SNAPC2, CTXN1, AC010336.5, TIMM44.
- chr19:27,638,483–30,029,916, 55 genes, copy number 10–36: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2.
- chr19:34,923,299–35,228,729, 21 genes, copy number 7: ZNF30-AS1, ZNF30, AC008555.6, ZNF792, GRAMD1A, AC020907.3, AC020907.4, SCN1B, HPN, HPN-AS1, AC020907.1, AC020907.6, FXYD3, MIR6887, LGI4, AC020907.5, FXYD1, AC020907.2, FXYD7, FXYD5, FAM187B.
- chr20:23,346,941–25,298,012, 61 genes, copy number 10–66 (within-gene range 4–66) (broad region; genes not listed).
- chr20:59,852,667–63,744,050, 121 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,638. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
